Somatic mutation profile of tumor specimen MP2PRT-PAVZIR-TMP1-A (aliquot MP2PRT-PAVZIR-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVZIR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,928 days).
Specimen MP2PRT-PAVZIR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f82bfdb-cfa7-4436-821f-5a55946a9fe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVZIR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVZIR-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0496db24-4e9b-4356-bc5a-f37ae39083b0

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPR1 | c.7760G>A p.G2587E (on ENST00000354582; = p.G2532E on NM_002222.7) | Missense Mutation (SNP) | VAF 70/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312685, CM158929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCAF8L2 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 20/381 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.721); catalogued as rs1168789529; called by muse, mutect2
- DOCK1 | c.4882C>T p.R1628C | Missense Mutation (SNP) | VAF 213/477 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1336971745; called by muse, mutect2, varscan2
- JAK1 | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61086746; called by muse, mutect2, varscan2
- CPS1 | c.3664A>T p.K1222* | Nonsense Mutation (SNP) | VAF 24/384 reads (6%) | called by muse, mutect2
- NCAM1 | c.2060A>G p.E687G (on ENST00000316851 / NM_181351.5; = p.E677G on NM_000615.7) | Missense Mutation (SNP) | VAF 201/428 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR1L1 | c.808A>G p.R270G (on ENST00000373686; = p.R220G on NM_001005236.3) | Missense Mutation (SNP) | VAF 87/458 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PARD3B | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 37/505 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.283); called by muse, mutect2
- PAX5 | c.1049_1058del p.Q350Rfs*50 | Frame Shift Del (DEL) | VAF 87/264 reads (33%) | called by mutect2, pindel, varscan2
- SCYL2 | c.2260A>G p.I754V | Missense Mutation (SNP) | VAF 203/413 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.258C>T p.I86= | Silent (SNP) | VAF 105/308 reads (34%) | catalogued as COSV62438633; called by muse, mutect2, varscan2
- CDH23 | c.2766C>T p.N922= | Silent (SNP) | VAF 46/584 reads (8%) | catalogued as rs371670151; called by muse, mutect2
- DNAI3 | c.954C>T p.T318= | Silent (SNP) | VAF 24/436 reads (6%) | catalogued as rs371237829; called by muse, mutect2
- IGHG4 | c.144C>T p.S48= | Silent (SNP) | VAF 177/1040 reads (17%) | catalogued as rs367653567; called by muse, varscan2
- KIF25 | c.933C>A p.G311= | Silent (SNP) | VAF 95/653 reads (15%) | called by muse, mutect2, varscan2
